CPTAC case C3L-02647 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8ec9b361-ed77-4809-8682-fac8864216c1

Demographics
Sex at birth: male; Race: white; Year of birth: 1949; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 69.1 years (25,244 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,805 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,805 days (4.9 years); Clark level: IV; Tumor focality: Unifocal; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >2.0-4.0 mm; Greatest tumor dimension: 1.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (5 entries)
- Days to follow up: 461 days (1.3 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 860 days (2.4 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,075 days (2.9 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,434 days (3.9 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,805 days (4.9 years); Disease response: Tumor Free; ECOG performance status: 0.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 40; Cigarettes per day: 20; Tobacco smoking onset year: 1978; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 44.

Biospecimens (8 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02647-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 36 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02647-21: Section location: Trunk; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-02647-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 26 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02647-22: Section location: Trunk; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-02647-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 29 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02647-23: Section location: Trunk; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-02647-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 40 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02647-24: Section location: Trunk; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-02647-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 68 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02647-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 50 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02647-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 6 days; Initial weight: 43 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02647-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 6 days; Method of sample procurement: Blood Draw.
